MMRF case MMRF_2055 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4530d2de-f148-49f2-b956-042630696607

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.6 years (30,907 days); ISS stage: III; Days to last known disease status: 977 days (2.7 years); Days to last follow up: 977 days (2.7 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 178 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 283 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 811 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 906 days (2.5 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 977.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 2): M Protein 2.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 24.1 mg/dL; Immunoglobulin G 28.4 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 8.4 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 14.3 mmol/L; Calcium 2.38 mmol/L; Albumin 32 g/L; Total Protein 8.8 g/dL; Glucose 7.54 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 94 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.62 mg/dL; Immunoglobulin G 5.5 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 5.6 µg/mL; Hemoglobin 4.96 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.93 mmol/L; Albumin 23 g/L; Total Protein 5 g/dL; Glucose 9.57 mmol/L.
- Day 178 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.05 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 6.3 µg/mL; Hemoglobin 5.27 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 6.1 g/dL; Glucose 9.35 mmol/L.
- Day 262 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.2 mg/dL; Immunoglobulin G 7.63 g/L; Immunoglobulin A 2.88 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 5.64 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.18 mmol/L; Albumin 32.9 g/L; Total Protein 6 g/dL; Glucose 4.84 mmol/L.
- Day 345 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Immunoglobulin G 7.97 g/L; Immunoglobulin A 2.65 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.2 mmol/L; Albumin 38.1 g/L; Total Protein 6.2 g/dL; Glucose 7.21 mmol/L.
- Day 430 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.31 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 2.27 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.18 mmol/L; Albumin 40.5 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 542 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 6.66 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 159 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 605 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 6.4 g/L; Immunoglobulin A 1.81 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 7.9 g/dL; Glucose 4.79 mmol/L.
- Day 717 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.83 mg/dL; Hemoglobin 6.01 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 4.84 mmol/L.
- Day 813 (ECOG 2): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 31.9 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 10.2 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.73 mmol/L; Albumin 44 g/L; Total Protein 7.7 g/dL; Glucose 4.79 mmol/L.
- Day 899 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.5 mg/dL; Hemoglobin 5.46 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.28 mmol/L; Albumin 30 g/L; Total Protein 6.4 g/dL; Glucose 5.23 mmol/L.
- Day 976 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 3.83 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 230 µmol/L; Blood Urea Nitrogen 14.6 mmol/L; Calcium 2.33 mmol/L; Albumin 36.9 g/L; Total Protein 5.7 g/dL; Glucose 6.27 mmol/L.

Other clinical attributes
- Day -7: Weight: 66 kg; Height: 150 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2055_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2055_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
